Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017973-09A.1 (aliquot TARGET-15-SJMPAL017973-09A.1-01D) from TARGET case TARGET-15-SJMPAL017973, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,657 days).
Specimen TARGET-15-SJMPAL017973-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fd9a79b-87f2-4c04-b1a3-db53a5f537eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017973-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL017973-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3643b3f6-d809-4325-8070-c984c47db509

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, RNA 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA5 | c.2941C>T p.R981W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755988244, COSV56650883; called by muse, mutect2, varscan2
- GPRASP1 | c.2874G>C p.E958D | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100850916; called by muse, mutect2, varscan2
- IFRD2 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100269249; called by muse, mutect2
- MDN1 | c.4746G>T p.M1582I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1245169165; called by muse, mutect2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 95/173 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2, varscan2
- ADAMTS4 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- BSN | c.5578C>A p.P1860T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2
- CABP1 | c.796C>A p.L266I (on ENST00000316803 / NM_001033677.1; = p.L63I on NM_004276.5) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- DMTF1 | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2
- FAM200A | c.1019G>T p.W340L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2
- ITPR1 | c.7334C>A p.A2445E (on ENST00000354582; = p.A2390E on NM_002222.7) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MON2 | c.3580C>A p.P1194T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PPP1R3A | c.2429G>T p.C810F | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.313); called by muse, mutect2
- RIPK3 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC43A2 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2
- GRIN2A | c.1035C>A p.G345= | Silent (SNP) | VAF 77/216 reads (36%) | called by muse, mutect2, varscan2
- HEY2 | c.906C>T p.A302= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as rs1322056557; called by muse, mutect2, varscan2
- PABPN1L | c.660G>T p.L220= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- SPEF1 | c.15G>T p.V5= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- TIMM10B | c.177C>A p.S59= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- VPS13C | c.8451A>G p.Q2817= (on ENST00000644861 / NM_020821.3; = p.Q2774= on NM_017684.5) | Silent (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- ZNF467 | c.522G>T p.T174= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- HOGA1 | c.468+82C>A | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- LINC00574 | n.15C>A | RNA (SNP) | VAF 3/35 reads (9%) | catalogued as rs1429287373; called by muse, mutect2
- RNU6-1178P | chr17:20895752 G>A | 5'Flank (SNP) | VAF 4/49 reads (8%) | catalogued as rs1203504940; called by muse, mutect2
